Somatic mutation profile of tumor specimen TCGA-GV-A6ZA-01A (aliquot TCGA-GV-A6ZA-01A-12D-A339-08) from TCGA case TCGA-GV-A6ZA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 54.4 years (19,871 days).
Specimen TCGA-GV-A6ZA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 303cea97-e6e0-42e5-8930-1248293dbccf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A6ZA-10A (Blood Derived Normal), aliquot TCGA-GV-A6ZA-10A-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75cde6b4-0a91-4b52-aec6-372381203253

The open-access MAF lists 340 somatic variants for this specimen: 261 protein-altering or splice-affecting, 71 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 231, Silent 71, Nonsense Mutation 20, Intron 6, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, Nonstop Mutation 2, Translation Start Site 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as rs1486082302, COSV60103144; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 208/241 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2329G>T p.V777L | Missense Mutation (SNP) | VAF 36/42 reads (86%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs121913471, COSV54062385, COSV54062767, COSV54069186; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.2793G>T p.L931F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV64986901; called by muse, mutect2, varscan2
- ABCC5 | c.4105C>G p.Q1369E | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1448900537, COSV55592334; called by muse, mutect2, varscan2
- ACAN | c.6566C>T p.P2189L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as COSV61363133; called by muse, mutect2, varscan2
- ACIN1 | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV52978006, COSV99075877; called by muse, mutect2, varscan2
- ADA | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63069028; called by muse, mutect2, varscan2
- ADAM17 | c.797C>G p.S266* | Nonsense Mutation (SNP) | VAF 46/133 reads (35%) | catalogued as COSV100176494; called by muse, mutect2, varscan2
- ADAT2 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV52794859; called by muse, mutect2, varscan2
- ADGRV1 | c.6833G>T p.G2278V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101316407, COSV67979265; called by muse, mutect2
- AFF4 | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs112871745, COSV54796199; called by muse, mutect2, varscan2
- ALG10 | c.1014G>C p.W338C | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56792911, COSV99847976; called by muse, mutect2, varscan2
- ALMS1 | c.8826G>C p.M2942I | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52513186; called by muse, mutect2, varscan2
- ALPK2 | c.3829G>C p.D1277H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV64491831, COSV64494084; called by muse, mutect2, varscan2
- APLF | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV58145879; called by muse, mutect2, varscan2
- ARHGAP11A | c.3055A>G p.K1019E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV55707025; called by mutect2, varscan2
- ARID1A | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61380895; called by muse, mutect2, varscan2
- ASH1L | c.6656G>A p.R2219Q (on ENST00000368346 / NM_001366177.2; = p.R2214Q on NM_018489.3) | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1224632413, COSV64209725; called by muse, mutect2, varscan2
- ASXL3 | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV99326243; called by muse, mutect2
- ATM | c.6976-1G>C p.X2326_splice | Splice Site (SNP) | VAF 14/18 reads (78%) | catalogued as COSV99591589; called by muse, mutect2, varscan2
- ATP8A1 | c.1397A>C p.N466T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV52538855; called by muse, mutect2, varscan2
- ATP9A | c.2689G>C p.D897H | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58768278; called by muse, mutect2, varscan2
- ATR | c.4465G>C p.E1489Q | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV63387869; called by muse, mutect2, varscan2
- BAG6 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.583); catalogued as COSV52992215; called by muse, mutect2, varscan2
- BAZ1B | c.2551C>T p.Q851* | Nonsense Mutation (SNP) | VAF 66/154 reads (43%) | catalogued as rs1554572869, COSV100290068; called by muse, mutect2, varscan2
- BCLAF3 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV61414235; called by muse, mutect2, varscan2
- BPTF | c.4121C>T p.S1374F | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.054); catalogued as COSV58840045; called by muse, mutect2, varscan2
- BRCA1 | c.1059G>C p.W353C | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs80356935, COSV58793089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58793095; called by muse, mutect2, varscan2
- C11orf65 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.799); catalogued as rs552038895, COSV67597794; called by muse, mutect2, varscan2
- C1QTNF5 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs906525288, COSV60990858; called by muse, mutect2, varscan2
- C1S | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61071280; called by muse, mutect2, varscan2
- C8A | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as rs1243071112, COSV63485004; called by muse, mutect2, varscan2
- CAT | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV53811642; called by muse, mutect2, varscan2
- CCDC92 | c.772A>T p.I258F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV53020333; called by muse, mutect2, varscan2
- CDH2 | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV52284902; called by muse, mutect2
- CDK5RAP3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58115388; called by muse, mutect2, varscan2
- CEACAM8 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54990962, COSV99747701; called by muse, mutect2, varscan2
- CENPU | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as COSV55658194; called by muse, mutect2
- CIITA | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.306); catalogued as rs777187047, COSV60858908; called by muse, mutect2, varscan2
- CNGB1 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99208867; called by muse, varscan2
- CNGB1 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV51902574; called by muse, varscan2
- CNOT1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100409942, COSV100409948; called by muse, mutect2, varscan2
- COL7A1 | c.7133C>T p.S2378F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs1411532691, COSV60395285; called by muse, mutect2, varscan2
- COL7A1 | c.2887C>T p.R963C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs773083989, COSV60399006; called by muse, mutect2, varscan2
- COLGALT2 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV62299816; called by muse, mutect2, varscan2
- CRACD | c.1245G>C p.W415C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs756732878, COSV51717180, COSV99949913; called by muse, mutect2, varscan2
- CSGALNACT2 | c.207G>C p.Q69H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); catalogued as COSV65675922; called by muse, mutect2, varscan2
- CST3 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100976881; called by muse, varscan2
- CTBP2 | c.872G>C p.R291P | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58332874, COSV58335054; called by muse, mutect2, varscan2
- CUBN | c.5578C>G p.H1860D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as COSV64719330; called by muse, mutect2, varscan2
- CUBN | c.3937A>G p.T1313A | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV100913419, COSV64719335; called by muse, mutect2
- CUEDC2 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56523467; called by muse, mutect2, varscan2
- CUL7 | c.3061G>T p.E1021* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV99539157; called by muse, mutect2, varscan2
- CXCL9 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT tolerated (0.76); PolyPhen benign (0.034); catalogued as COSV53579166, COSV99345607; called by muse, mutect2, varscan2
- CYP3A43 | c.1134G>C p.K378N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs545846456, COSV55936711; called by muse, varscan2
- DCDC1 | c.4053G>C p.K1351N (on ENST00000597505 / NM_001367979.1; = p.K458N on NM_020869.3) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV58000212; called by muse, mutect2, varscan2
- DEF6 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57354466; called by muse, mutect2, varscan2
- DENND4A | c.4619C>G p.S1540C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV71266256; called by muse, mutect2, varscan2
- DENND4C | c.5275C>T p.H1759Y (on ENST00000434457 / NM_001330640.2; = p.H1710Y on NM_017925.7) | Missense Mutation (SNP) | VAF 75/95 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as rs766737164, COSV63009148; called by muse, mutect2, varscan2
- DGKE | c.1199G>C p.R400T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1439519433, COSV52350265, COSV99401081; called by muse, mutect2, varscan2
- DHX57 | c.3604G>C p.E1202Q | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV54886945; called by muse, mutect2, varscan2
- DNAH6 | c.2038A>T p.R680* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99408435; called by muse, mutect2, varscan2
- DST | c.19510C>G p.Q6504E (on ENST00000361203 / NM_001374722.1; = p.Q4201E on NM_015548.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.946); catalogued as rs1340209360, COSV99756123, COSV99759360; called by muse, mutect2, varscan2
- EIF2B3 | c.762G>C p.K254N | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV64517819; called by muse, mutect2, varscan2
- EIF2B4 | c.239C>G p.S80W (on ENST00000347454 / NM_001034116.2; = p.S79W on NM_015636.3) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV52008588; called by muse, mutect2, varscan2
- FAM102B | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100899362; called by muse, mutect2, varscan2
- FAM135B | c.4192T>G p.L1398V | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52734252; called by muse, mutect2
- FANCM | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | catalogued as COSV99361139; called by muse, mutect2, varscan2
- FASLG | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV60680352; called by muse, mutect2, varscan2
- FBXL2 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52139971; called by muse, mutect2, varscan2
- FBXL2 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52139986; called by muse, mutect2, varscan2
- FEN1 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57251011; called by muse, mutect2, varscan2
- FGA | c.432A>C p.K144N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as CD001895, COSV57397552; called by muse, mutect2
- FGD3 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV61598325; called by muse, mutect2, varscan2
- FUT2 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67179462; called by muse, mutect2, varscan2
- GALNT11 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57426731; called by muse, mutect2, varscan2
- GHITM | c.552G>C p.Q184H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV64538736; called by muse, mutect2, varscan2
- GLYATL1 | c.299G>T p.R100I (on ENST00000317391 / NM_001354699.1; = p.R131I on NM_080661.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV55609135, COSV55609621; called by muse, mutect2, varscan2
- GNAS | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV55679699, COSV55681483; called by muse, mutect2
- GNG12 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV63972354, COSV63972986; called by muse, mutect2, varscan2
- GPR153 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64938687; called by muse, mutect2, varscan2
- IFNL2 | c.602G>C p.*201Sext*13 | Nonstop Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100122126; called by muse, mutect2, varscan2
- IGHV3-72 | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.42); catalogued as COSV70409673; called by muse, mutect2, varscan2
- IMPG2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV51980444, COSV51984350; called by muse, mutect2, varscan2
- INTS2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.075); catalogued as COSV52154129; called by muse, mutect2, varscan2
- ITGA7 | c.3165G>C p.L1055F (on ENST00000555728; = p.L1011F on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV57696802; called by muse, mutect2, varscan2
- ITGAV | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as COSV53714576; called by muse, mutect2, varscan2
- ITPR2 | c.4595C>T p.S1532L | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV67271278; called by muse, mutect2, varscan2
- ITPR3 | c.5710G>A p.V1904I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100968032; called by muse, mutect2
- ITSN2 | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.527); catalogued as COSV61949441; called by muse, mutect2, varscan2
- KCNA1 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101230310, COSV66837856; called by muse, mutect2, varscan2
- KCNH1 | c.679T>G p.L227V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55070444; called by muse, mutect2
- KCNJ8 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as rs142014286, COSV53715143; called by muse, mutect2, varscan2
- KDM6A | c.3558G>C p.L1186F | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV65042188; called by muse, mutect2
- KDM6A | c.3644G>C p.G1215A | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65037190, COSV65042194, COSV99060786; called by muse, mutect2, varscan2
- KLRC2 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.82); catalogued as COSV101122735; called by muse, mutect2
- KMT2D | c.16549G>C p.E5517Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56454952; called by muse, mutect2, varscan2
- KTN1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779998905, COSV68024113; called by muse, mutect2, varscan2
- LAMA4 | c.2595G>A p.M865I (on ENST00000230538 / NM_001105206.3; = p.M858I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV57899571; called by muse, mutect2, varscan2
- LMBR1 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.69); catalogued as rs764846509, COSV62221201; called by muse, mutect2, varscan2
- LRFN4 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.306); catalogued as rs1321815031, COSV58921975; called by muse, mutect2, varscan2
- LRRC6 | c.507C>G p.I169M | Missense Mutation (SNP) | VAF 95/111 reads (86%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV51543762; called by muse, mutect2, varscan2
- LSM14B | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV53381767; called by muse, mutect2, varscan2
- LSS | c.2037G>C p.E679D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62701516; called by muse, mutect2, varscan2
- MACC1 | c.1952C>G p.S651* | Nonsense Mutation (SNP) | VAF 35/79 reads (44%) | catalogued as COSV100256222; called by muse, mutect2, varscan2
- MAN2A1 | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.337); catalogued as COSV54854035; called by muse, mutect2, varscan2
- MAP1S | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV60723294; called by muse, mutect2, varscan2
- MAP3K19 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59640121; called by muse, mutect2, varscan2
- MAST1 | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52249095; called by muse, mutect2, varscan2
- MCM10 | c.1862C>A p.P621Q (on ENST00000484800 / NM_182751.3; = p.P620Q on NM_018518.5) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.615); catalogued as COSV101098407; called by muse, varscan2
- MCMBP | c.1179G>C p.L393F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV63509506; called by muse, mutect2, varscan2
- MDH1 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs756717360, COSV51863890; called by muse, mutect2, varscan2
- MPDU1 | c.744G>C p.*248Yext*41 | Nonstop Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100002189; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1896G>C p.K632N | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV100825235, COSV64056136; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV56621085; called by muse, mutect2, varscan2
- MUC16 | c.16394C>A p.S5465Y | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV67475685; called by muse, mutect2, varscan2
- MUC17 | c.2646C>G p.I882M | Missense Mutation (SNP) | VAF 185/426 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV60292942; called by muse, mutect2, varscan2
- MVP | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV62422455; called by muse, varscan2
- MYO1E | c.2331C>G p.F777L | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55689792; called by muse, mutect2, varscan2
- NAGK | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1249360768, COSV54903918, COSV99730442; called by muse, mutect2, varscan2
- NAP1L5 | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV52021642; called by muse, mutect2, varscan2
- NCBP3 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs767928576, COSV50108452; called by muse, mutect2, varscan2
- NCOA1 | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56047284; called by muse, mutect2, varscan2
- NDUFS1 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51911010; called by muse, mutect2, varscan2
- NEB | c.19921C>T p.Q6641* | Nonsense Mutation (SNP) | VAF 62/137 reads (45%) | catalogued as COSV99427214; called by muse, mutect2, varscan2
- NEK4 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV51781172; called by muse, mutect2, varscan2
- NEK4 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV51781187; called by muse, mutect2, varscan2
- NEXMIF | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV50023537, COSV99281679; called by muse, mutect2, varscan2
- NEXN | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.08); catalogued as rs794729082, COSV53943557, COSV99630297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFE2L3 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV50230895; called by muse, mutect2, varscan2
- NID2 | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766009521, COSV53498387; called by muse, mutect2
- NKD1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); catalogued as rs375195685; called by muse, mutect2, varscan2
- NOS1 | c.2223-1G>A p.X741_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100501299, COSV57613268; called by muse, mutect2, varscan2
- NOS1AP | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100723578; called by muse, mutect2
- NOS3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369489094; called by muse, mutect2, varscan2
- NPC1 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs1445395151, COSV52580041; called by muse, mutect2, varscan2
- NSUN5 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs782148643, COSV53092243; called by muse, mutect2, varscan2
- OAF | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61109476; called by muse, mutect2, varscan2
- OLFM3 | c.1375G>A p.G459S (on ENST00000338858 / NM_001288821.1; = p.G439S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV58800374; called by muse, mutect2, varscan2
- OPA1 | c.2551G>C p.E851Q (on ENST00000361510 / NM_130837.3; = p.E796Q on NM_015560.3) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100655450; called by muse, mutect2, varscan2
- OR10H2 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV59946294; called by muse, mutect2, varscan2
- OR10H2 | c.681G>C p.L227F | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV59946313; called by muse, mutect2, varscan2
- OR1A1 | c.812T>A p.V271E | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58404057; called by muse, mutect2
- OR2L2 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV63555311; called by muse, mutect2, varscan2
- OR4X1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100186637, COSV60723240; called by muse, mutect2
- OR5F1 | c.555C>G p.F185L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV53547177; called by muse, mutect2, varscan2
- OSBPL1A | c.2842G>A p.D948N (on ENST00000319481 / NM_080597.4; = p.D435N on NM_018030.4) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV59111487; called by muse, mutect2, varscan2
- OSBPL7 | c.1997C>T p.S666F | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as rs776997509, COSV50110265; called by muse, mutect2, varscan2
- OVCH1 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as COSV100548425, COSV100549122; called by muse, mutect2, varscan2
- PAK3 | c.384G>C p.K128N (on ENST00000262836 / NM_001324328.2; = p.K113N on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV53276429; called by muse, mutect2, varscan2
- PANX1 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as rs1160760425, COSV57134232; called by muse, mutect2, varscan2
- PAPPA2 | c.3670C>G p.P1224A | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV62801425; called by muse, mutect2, varscan2
- PARP4 | c.4861G>C p.E1621Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV67962740; called by muse, mutect2, varscan2
- PCDH11Y | c.2653G>C p.E885Q (on ENST00000400457 / NM_032973.2; = p.E874Q on NM_032971.3) | Missense Mutation (SNP) | VAF 63/71 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53083814; called by muse, mutect2, varscan2
- PCDHA1 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.101); catalogued as COSV65375052; called by muse, mutect2, varscan2
- PDHA1 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58832770; called by muse, mutect2
- PFKFB3 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 8/14 reads (57%) | PolyPhen probably damaging (0.994); catalogued as rs746812707, COSV100432320; called by muse, varscan2
- PHF7 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); catalogued as COSV59980660; called by muse, mutect2, varscan2
- PKN2 | c.2377G>C p.E793Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.864); catalogued as COSV65143407; called by muse, mutect2, varscan2
- PLK1 | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55621503, COSV55622720; called by muse, mutect2, varscan2
- PNPT1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV53178103, COSV99569778; called by muse, mutect2, varscan2
- PNPT1 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV53178119; called by muse, mutect2, varscan2
- POLE | c.4777C>G p.L1593V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV57683494; called by muse, mutect2, varscan2
- PPIP5K2 | c.1803G>C p.M601I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV58606833; called by muse, mutect2, varscan2
- PPM1L | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214162439, COSV55565633; called by muse, mutect2, varscan2
- PPTC7 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV62826392; called by muse, mutect2, varscan2
- PTPDC1 | c.892G>C p.D298H (on ENST00000375360 / NM_177995.3; = p.D350H on NM_152422.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56624091, COSV99997299; called by muse, mutect2, varscan2
- PTPN21 | c.1567C>G p.P523A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.997); catalogued as COSV60849370, COSV60853412; called by muse, mutect2, varscan2
- PUS10 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV57453212; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RBM14 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV59559507, COSV59559588; called by muse, mutect2, varscan2
- RIC8A | c.1078C>G p.L360V (on ENST00000526104 / NM_001286134.1; = p.L366V on NM_021932.5) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57343400; called by muse, mutect2, varscan2
- RIOX1 | c.1181G>C p.G394A | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242038982, COSV100408106; called by muse, mutect2, varscan2
- RIOX1 | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as COSV100408109; called by muse, mutect2, varscan2
- RIPK4 | c.1318G>A p.E440K (on ENST00000352483; = p.E392K on NM_020639.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV60188108; called by muse, mutect2, varscan2
- RPGRIP1L | c.2779A>G p.I927V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1397297818, COSV50909097; called by muse, mutect2, varscan2
- RSF1 | c.3418G>A p.D1140N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as COSV57841856; called by muse, mutect2, varscan2
- RTKN | c.1354G>A p.E452K (on ENST00000272430 / NM_001015055.2; = p.E439K on NM_033046.2) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV51964431; called by muse, varscan2
- RYR1 | c.14818G>T p.A4940S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CM030715, COSV62101354; called by muse, mutect2, varscan2
- SAP18 | c.223G>C p.E75Q (on ENST00000607003; = p.E94Q on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV66822820; called by muse, mutect2, varscan2
- SCRIB | c.3865G>A p.G1289R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as COSV57589071; called by muse, mutect2, varscan2
- SERPINA6 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs766474893, COSV58585813, COSV58586331; called by muse, mutect2, varscan2
- SHD | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1568368453, COSV101619074, COSV73378744; called by muse, mutect2, varscan2
- SIN3B | c.2879G>A p.R960H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs769504888, COSV56134239; called by muse, mutect2, varscan2
- SLC6A3 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1411494113, COSV54365723, COSV99548106; called by muse, mutect2, varscan2
- SLC9A4 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376409344; called by mutect2, varscan2
- SLITRK2 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1313895330, COSV59426603; called by muse, mutect2, varscan2
- SMARCA2 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV61809138; called by muse, mutect2, varscan2
- SMYD4 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59712100; called by muse, mutect2, varscan2
- SP8 | c.110C>T p.S37L (on ENST00000361443 / NM_198956.4; = p.S55L on NM_182700.6) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs201512381; called by muse, mutect2, varscan2
- SPATA2L | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV57047497; called by muse, mutect2, varscan2
- SPRED2 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.922); catalogued as rs758753744, COSV62693630; called by muse, mutect2, varscan2
- SPTA1 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV63754117, COSV63759555; called by muse, mutect2, varscan2
- SPTAN1 | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV63987443; called by muse, varscan2
- SPTAN1 | c.5965G>T p.E1989* | Nonsense Mutation (SNP) | VAF 12/14 reads (86%) | catalogued as COSV100823962; called by muse, varscan2
- SRMS | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0.072); catalogued as COSV53917351; called by muse, mutect2, varscan2
- STARD7 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61526172; called by muse, mutect2, varscan2
- STAT1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV63116609; called by muse, mutect2, varscan2
- STON1 | c.1613G>T p.G538V | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139601940; called by muse, mutect2, varscan2
- STRAP | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as COSV99214723, COSV99214917; called by muse, mutect2, varscan2
- SUCNR1 | c.998A>C p.E333A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV62912444; called by muse, mutect2
- SYNE1 | c.8790G>A p.W2930* (on ENST00000367255 / NM_182961.4; = p.W2937* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 44/75 reads (59%) | catalogued as COSV99576303; called by muse, mutect2, varscan2
- SYNJ1 | c.3145G>C p.D1049H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1340800145, COSV59150710; called by muse, mutect2, varscan2
- SYTL2 | c.2361G>C p.K787N (on ENST00000528231 / NM_001162951.2; = p.K763N on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV100314834; called by muse, mutect2, varscan2
- TAAR5 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV57799340, COSV57799648; called by muse, mutect2, varscan2
- TANC2 | c.2021C>G p.S674C | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67336512; called by muse, mutect2, varscan2
- TAS2R20 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV101115186, COSV101115500; called by muse, mutect2
- TBKBP1 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.147); catalogued as COSV64653934; called by muse, mutect2, varscan2
- TFPI2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs543669576, COSV55990653; called by muse, mutect2, varscan2
- TIAM2 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV59696752; called by muse, mutect2, varscan2
- TIMELESS | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99974281; called by muse, mutect2, varscan2
- TJP2 | c.2507C>A p.S836Y | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55269119; called by muse, mutect2, varscan2
- TM2D1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV53907488; called by muse, mutect2, varscan2
- TMC7 | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.448); catalogued as COSV58584700; called by muse, mutect2, varscan2
- TP53BP1 | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 68/129 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV55501947, COSV55503619; called by muse, mutect2, varscan2
- TRAPPC8 | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs1269852922, COSV51977732, COSV99351865; called by muse, mutect2, varscan2
- TRIM21 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as COSV99587883; called by muse, mutect2
- TRPM2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV55968418; called by muse, mutect2, varscan2
- TST | c.459C>G p.F153L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV50765226; called by muse, mutect2, varscan2
- TTC37 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 36/67 reads (54%) | catalogued as COSV100706840; called by muse, mutect2, varscan2
- TTC39C | c.895G>A p.E299K (on ENST00000317571 / NM_001135993.2; = p.E238K on NM_153211.4) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV58218567; called by muse, mutect2, varscan2
- TTN | c.94039G>A p.E31347K (on ENST00000591111; = p.E23923K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | PolyPhen possibly damaging (0.654); catalogued as COSV100626993, COSV60048446; called by muse, mutect2, varscan2
- TTN | c.65756G>A p.G21919D (on ENST00000591111; = p.G14495D on NM_003319.4) | Missense Mutation (SNP) | VAF 55/111 reads (50%) | PolyPhen probably damaging (1); catalogued as rs1458227087, COSV60151053; called by muse, mutect2, varscan2
- TTN | c.25564A>T p.I8522L (on ENST00000591111; = p.I7595L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | PolyPhen benign (0); catalogued as COSV60151108; called by muse, mutect2, varscan2
- TXNIP | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as COSV65220406, COSV65220753; called by muse, mutect2, varscan2
- UBD | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100590003, COSV63541984; called by muse, mutect2, varscan2
- UBE2R2 | c.534G>C p.K178N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV54290594; called by muse, mutect2, varscan2
- UBE4A | c.1175C>T p.S392F (on ENST00000252108 / NM_001204077.2; = p.S399F on NM_004788.4) | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52805020; called by muse, mutect2, varscan2
- UNC13D | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776737156, CM112830, COSV52884054; called by muse, varscan2
- UPF3A | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100677691; called by muse, mutect2, varscan2
- USP29 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.735); catalogued as COSV54240889; called by muse, mutect2, varscan2
- USP33 | c.1282T>C p.S428P | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV62470056; called by muse, mutect2, varscan2
- USP8 | c.597G>C p.L199F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV56165412; called by muse, mutect2, varscan2
- VEPH1 | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62879993; called by muse, mutect2
- VKORC1L1 | c.469T>G p.Y157D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62489602; called by muse, mutect2, varscan2
- VPS72 | c.376G>A p.G126S | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.094); catalogued as rs148105499; called by muse, mutect2, varscan2
- VWF | c.2914G>A p.V972M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs150418484; called by muse, mutect2, varscan2
- WDCP | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54592763; called by muse, mutect2, varscan2
- WNK1 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60037150; called by muse, mutect2, varscan2
- XPO6 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as rs1488341539, COSV58963292; called by muse, mutect2
- ZBTB41 | c.2722C>G p.H908D | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV66359374; called by muse, mutect2, varscan2
- ZBTB45 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54020337; called by muse, mutect2, varscan2
- ZFP90 | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV68051065; called by muse, mutect2, varscan2
- ZFYVE9 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as rs766452753, COSV55095571; called by muse, mutect2, varscan2
- ZGRF1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV52201486; called by muse, mutect2, varscan2
- ZKSCAN8 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV57639023; called by muse, mutect2, varscan2
- ZNF155 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV54207332; called by muse, mutect2, varscan2
- ZNF292 | c.5012C>T p.S1671L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV100371045; called by muse, mutect2
- ZNF419 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 37/94 reads (39%) | catalogued as COSV55661188; called by muse, mutect2, varscan2
- ZNF532 | c.1122G>C p.K374N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60174051; called by muse, mutect2, varscan2
- ZNF532 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.388); catalogued as COSV60174058; called by muse, mutect2, varscan2
- ZNF587 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 55/126 reads (44%) | catalogued as COSV100299645; called by muse, mutect2, varscan2
- ZNF780A | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV61815747; called by muse, mutect2, varscan2
- CHD2 | c.1880_1883del p.S627Yfs*6 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- ELF3 | c.618dup p.S207Lfs*10 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | called by mutect2, pindel
- FAT1 | c.10672_10676del p.E3558Lfs*17 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, varscan2
- PTPRD | c.1424A>G p.Q475R | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2
- RTKN | c.968dup p.M324Dfs*23 (on ENST00000272430 / NM_001015055.2; = p.M311Dfs*23 on NM_033046.2) | Frame Shift Ins (INS) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- SCAP | c.99_102del p.G34Sfs*4 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- ABCA8 | c.3375C>T p.F1125= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV52204551, COSV99284413; called by muse, mutect2, varscan2
- ABTB1 | c.1413C>T p.L471= (on ENST00000232744 / NM_172027.3; = p.L329= on NM_032548.3) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs767206309, COSV99230086; called by muse, varscan2
- ADGRV1 | c.786C>A p.P262= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV67988410; called by muse, varscan2
- ALPP | c.984C>T p.F328= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV67396822; called by muse, mutect2, varscan2
- ARAP3 | c.1908C>G p.L636= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV53351712; called by muse, mutect2, varscan2
- ARFGEF2 | c.2199C>T p.F733= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV64213189; called by muse, mutect2, varscan2
- ARVCF | c.705C>T p.A235= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV54269905, COSV99599497; called by muse, mutect2, varscan2
- ATXN7L2 | c.855G>A p.L285= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV63992302; called by muse, mutect2, varscan2
- C3orf18 | c.213G>C p.V71= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV51750882; called by muse, mutect2, varscan2
- CACNA1H | c.2334C>T p.L778= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs1461848475, COSV61994641; called by muse, mutect2, varscan2
- CCP110 | c.195T>C p.D65= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV66817227; called by muse, mutect2, varscan2
- CHAF1B | c.198C>G p.T66= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV58440491; called by muse, mutect2, varscan2
- CKAP5 | c.96G>A p.L32= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as COSV56369640; called by muse, mutect2, varscan2
- COX16 | c.48C>G p.L16= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV101112183, COSV66303078; called by muse, mutect2, varscan2
- CST3 | c.375C>T p.F125= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1182335529, COSV65362070; called by muse, varscan2
- CUX2 | c.2409G>A p.V803= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs758742538, COSV55637195; called by muse, mutect2, varscan2
- CYP3A43 | c.1182G>A p.V394= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV55936188; called by muse, varscan2
- DCLK2 | c.1533C>T p.I511= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs755611045, COSV56205830; called by muse, mutect2, varscan2
- EDNRA | c.1257G>C p.R419= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV60098426; called by muse, varscan2
- FAM107B | c.273G>A p.R91= | Silent (SNP) | VAF 47/220 reads (21%) | catalogued as COSV51682207, COSV51688959; called by muse, mutect2, varscan2
- FGD1 | c.1521G>C p.L507= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as COSV64309004; called by muse, mutect2, varscan2
- FSCN3 | c.1011G>A p.T337= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs576840283, COSV56170646; called by muse, mutect2, varscan2
- GABRA4 | c.1530T>G p.P510= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV51926115; called by muse, mutect2
- GARS1 | c.1545G>A p.V515= | Silent (SNP) | VAF 59/135 reads (44%) | catalogued as rs1001474075, COSV66828664; called by muse, mutect2, varscan2
- GTF3C1 | c.3024C>T p.C1008= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs750920671, COSV62242299; called by muse, mutect2, varscan2
- H1-4 | c.567G>C p.A189= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1397059282, COSV56800282, COSV56801664, COSV56803584; called by muse, mutect2, varscan2
- HECW1 | c.2022C>T p.D674= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs963677639, COSV101223045, COSV67840859; called by muse, mutect2
- HELZ2 | c.7044C>T p.S2348= (on ENST00000467148 / NM_001037335.2; = p.S1779= on NM_033405.3) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV64442989; called by muse, mutect2, varscan2
- IQCA1 | c.156C>A p.I52= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV54505131; called by muse, mutect2, varscan2
- KANK2 | c.1092G>C p.L364= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV62008734; called by muse, mutect2, varscan2
- KDM5A | c.2490C>G p.V830= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as COSV66993706; called by muse, mutect2, varscan2
- KIAA1549L | c.4023A>G p.L1341= (on ENST00000321505; = p.L1638= on NM_012194.3) | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV58591792; called by muse, mutect2
- KMT2D | c.15585G>A p.Q5195= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56420838, COSV56454982; called by muse, mutect2, varscan2
- LMTK2 | c.3615G>A p.L1205= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV51998401; called by muse, mutect2, varscan2
- MCM7 | c.142C>T p.L48= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV57995793, COSV57997172; called by muse, mutect2, varscan2
- MVP | c.2280G>A p.Q760= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs1398617448, COSV62422450; called by muse, varscan2
- MYOM1 | c.307C>T p.L103= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99868121; called by muse, mutect2, varscan2
- NSG2 | c.477C>T p.V159= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs747207528, COSV57458412; called by muse, mutect2, varscan2
- OPN3 | c.489C>G p.L163= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs985701088, COSV59365333; called by muse, mutect2, varscan2
- OR10H2 | c.594G>A p.L198= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV59946304; called by muse, mutect2
- OR1M1 | c.696C>T p.G232= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs142350139; called by muse, mutect2, varscan2
- OR2Y1 | c.249C>T p.I83= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57136837; called by muse, mutect2, varscan2
- OR5T3 | c.837T>G p.A279= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs781773301, COSV57381322; called by muse, mutect2
- OR6K2 | c.678T>C p.I226= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV62743091; called by muse, mutect2, varscan2
- PARP3 | c.732G>A p.T244= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as rs753716622, COSV51755116; called by muse, mutect2, varscan2
- PAX2 | c.69C>T p.L23= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as CD118561, COSV62291723; called by muse, mutect2, varscan2
- PDE10A | c.2154G>A p.K718= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV63099670; called by muse, mutect2, varscan2
- PHACTR3 | c.1266C>T p.F422= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV63030062; called by muse, mutect2, varscan2
- PLA2G4A | c.1612C>T p.L538= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV66552635; called by muse, mutect2, varscan2
- PLXNA3 | c.4389G>C p.L1463= | Silent (SNP) | VAF 39/43 reads (91%) | catalogued as COSV63754539; called by muse, mutect2, varscan2
- PNPLA6 | c.426C>G p.L142= (on ENST00000414982 / NM_001166111.2; = p.L94= on NM_006702.5) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV51176963, COSV51177905; called by muse, mutect2, varscan2
- PROKR1 | c.606C>T p.T202= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs1008650835, COSV58138068; called by muse, mutect2, varscan2
- RELT | c.306G>A p.G102= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV50361687; called by muse, mutect2, varscan2
- RIPOR3 | c.408C>T p.I136= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV50386801; called by muse, mutect2, varscan2
- SEMA6C | c.1473C>T p.I491= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV59004629; called by muse, mutect2, varscan2
- SERPINB3 | c.1161C>T p.F387= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV52192377, COSV52192889; called by muse, mutect2, varscan2
- SLC25A47 | c.591C>T p.F197= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs374854892; called by muse, mutect2, varscan2
- SLC2A10 | c.1401C>T p.L467= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as rs774586341, COSV63715117; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC5A1 | c.1170C>T p.L390= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV56686453, COSV56689317; called by muse, mutect2, varscan2
- SLFN13 | c.1428C>G p.L476= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV53193236; called by muse, mutect2, varscan2
- SLX4 | c.5352G>A p.E1784= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs1336931310, COSV53565367; called by muse, mutect2, varscan2
- TAGLN | c.321C>T p.I107= | Silent (SNP) | VAF 40/54 reads (74%) | catalogued as COSV54063597; called by muse, mutect2, varscan2
- TBX18 | c.1434C>T p.F478= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV63736281; called by muse, mutect2, varscan2
- TM2D1 | c.129G>A p.E43= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53907528; called by muse, mutect2, varscan2
- TRPM2 | c.759G>C p.L253= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as COSV55971784; called by muse, mutect2, varscan2
- TSPAN2 | c.486T>C p.P162= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as rs749902293, COSV65690146; called by muse, mutect2, varscan2
- TTN | c.63417C>G p.L21139= (on ENST00000591111; = p.L13715= on NM_003319.4) | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV60151078; called by muse, mutect2, varscan2
- UNC5D | c.1500G>A p.E500= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs200892724, COSV54806194; called by muse, mutect2, varscan2
- UTP4 | c.1245C>G p.L415= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV58733406; called by muse, mutect2, varscan2
- XIRP2 | c.3798C>T p.V1266= (on ENST00000628543; = p.V1441= on NM_152381.6) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV54710975, COSV99744352; called by muse, mutect2, varscan2
- XYLT1 | c.2436G>A p.L812= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1185749033, COSV54488047; called by muse, mutect2, varscan2
- ANKRD10 | c.456-913C>T | Intron (SNP) | VAF 20/67 reads (30%) | catalogued as COSV57444324; called by muse, mutect2, varscan2
- CCDC30 | c.385-6224C>G | Intron (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100501629; called by muse, mutect2, varscan2
- CSH1 | c.457-57G>C | Intron (SNP) | VAF 45/116 reads (39%) | catalogued as COSV60242500; called by muse, mutect2, varscan2
- LAMA3 | c.4998+1398G>A | Intron (SNP) | VAF 27/71 reads (38%) | catalogued as COSV52537236; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86024C>T | Intron (SNP) | VAF 48/90 reads (53%) | catalogued as COSV72283448; called by muse, mutect2, varscan2
- SLC25A3 | c.645-105_645-98del | Intron (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- UNK | c.-43G>C | 5'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as COSV53143356; called by muse, varscan2
- VPS26C | chr21:37221503 G>C | 3'Flank (SNP) | VAF 33/92 reads (36%) | catalogued as rs1164320152; called by muse, mutect2, varscan2
